Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HK, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HK-01A (Primary Tumor).

ICD-0-3
Carcinoma, squamous cell NOS
Site (L) Lung, upper & lower lobes C34.8
JW 2/1/13

Synoptic translated report

Site : Left lung superior lobe (basal segment)
and left lung inferior lobe (apical segment)

☐ Central ☒ Peripheral ☐ NA

Number of lesion :
1. Lung squamous cell carcinoma

Tumor size:
1. 6.0 x 6.0 x 5.5 cm

Visceral pleural invasion: ☒ Yes ☐ No ☐ NA

Chest wall invasion : ☒ Yes ☐ No ☐ NA

Histological diagnosis : Poorly differentiated squamous cell carcinoma

Node status : NO (0/35)

TNM : pT3 pN0 (0/35) G3 R0

Pathologist signature:

Date:

HPV Discrepancy		☒

Source: NCI Genomic Data Commons file a96d055f-ce9c-4249-b741-2065febe7564 (TCGA-NC-A5HK.074EAC41-3FC0-4686-8408-44B8351EE5C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).